Gene-level copy-number profile of tumor specimen TCGA-ZB-A966-01A from TCGA case TCGA-ZB-A966, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 78.4 years (28,621 days).
Specimen TCGA-ZB-A966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.1f5ca70c-eecc-4458-959a-306c45b07d6b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZB-A966-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c50819cf-3039-4a5d-85c6-4e66ff2ced0e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,600; copy number 3: 4; copy number 4: 52,823; copy number 6: 4,389.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZB-A966-01A-11D-A427-01): tumor purity 0.63, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
